Somatic mutation profile of tumor specimen MMRF_2769_1_BM_CD138pos (aliquot MMRF_2769_1_BM_CD138pos_T1_KHS5U_L15720) from MMRF case MMRF_2769, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,588 days).
Specimen MMRF_2769_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 282f38dd-5ca4-4a68-aa4f-03c739259cd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2769_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2769_1_PB_WBC_C3_KHS5U_L15764; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c415b54-5232-4dcd-a40e-a39bbed00551

The open-access MAF lists 81 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 23, Intron 12, Silent 5, RNA 4, 5'Flank 4, 5'UTR 3, 3'Flank 3, Splice Site 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DZIP1L | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555349004; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HSPBP1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224933821, COSV55335425; called by muse, mutect2, varscan2
- NLRP3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs199637520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP7 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs763024128, COSV60172066, COSV60182364; called by muse, mutect2, varscan2
- RBM25 | c.1931G>A p.C644Y | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as rs745544056; called by muse, mutect2, varscan2
- RIMS2 | c.3166C>G p.P1056A (on ENST00000666250 / NM_001348490.2; = p.P864A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.069); catalogued as COSV51677129; called by muse, mutect2, varscan2
- ST8SIA2 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 17/284 reads (6%) | PolyPhen possibly damaging (0.673); catalogued as rs766684400; called by muse, mutect2
- STAB2 | c.5984C>T p.T1995M | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763174579; called by muse, mutect2, varscan2
- ZNF835 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1408442056, COSV73379247; called by muse, mutect2, varscan2
- ANKAR | c.888A>T p.K296N | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CBLB | c.1490T>A p.L497H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL6A2 | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP2 | c.2387T>C p.L796P (on ENST00000075322 / NM_001040092.3; = p.L848P on NM_006209.5) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRK | c.1293A>T p.K431N | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- GPR158 | c.2395A>C p.T799P | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GPR158 | c.2912A>C p.Q971P | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, varscan2
- IGLL5 | c.324_325+3delinsGAGTG | Splice Region (ONP) | VAF 11/29 reads (38%) | called by pindel, varscan2*
- IQCA1 | c.926+1G>C p.X309_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- KLHL1 | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MC1R | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- OCA2 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PKHD1 | c.2692G>C p.A898P | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PSMC6 | c.757+7A>C | Splice Region (SNP) | VAF 67/146 reads (46%) | called by muse, mutect2, varscan2
- SHROOM2 | c.2790+1G>A p.X930_splice | Splice Site (SNP) | VAF 50/56 reads (89%) | called by muse, mutect2, varscan2
- TULP4 | c.4193A>C p.K1398T | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CCND1 | c.27A>G p.E9= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV57121168; called by muse, mutect2, varscan2
- CDK13 | c.69G>A p.E23= | Silent (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- DDX60L | c.310A>C p.R104= | Silent (SNP) | VAF 114/266 reads (43%) | called by muse, mutect2, varscan2
- IL17REL | c.90C>T p.R30= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs757922708; called by muse, mutect2, varscan2
- TTC6 | c.816G>A p.V272= | Silent (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- ADAD1 | c.172+91C>T | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ADAM22 | c.992+277A>T | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- ANXA1 | c.-14-373T>A | Intron (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- ARPIN | c.*1830T>C | 3'UTR (SNP) | VAF 85/210 reads (40%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021136 T>G | 5'Flank (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- BLNK | c.677-28G>T | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- BSCL2 | chr11:62709157 T>C | 5'Flank (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- BTBD3 | c.*2745C>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- C14orf177 | n.508G>A | RNA (SNP) | VAF 65/146 reads (45%) | catalogued as rs759775875, COSV100362743; called by muse, mutect2, varscan2
- CALU | c.-11-507C>G | Intron (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- CBLL1 | c.*52C>T | 3'UTR (SNP) | VAF 119/283 reads (42%) | catalogued as rs759744039; called by muse, mutect2, varscan2
- CBX7 | c.*1001T>A | 3'UTR (SNP) | VAF 68/139 reads (49%) | called by muse, mutect2, varscan2
- CCND1 | c.-97A>G | 5'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- CCSER1 | c.*2346A>G | 3'UTR (SNP) | VAF 20/60 reads (33%) | catalogued as rs1311167425; called by muse, mutect2, varscan2
- CMC1 | c.*5324C>A | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- CRISP3 | chr6:49728053 T>A | 3'Flank (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- DGKB | c.*1846T>A | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- DNMBP | c.*173T>C | 3'UTR (SNP) | VAF 30/87 reads (34%) | catalogued as rs906806270; called by muse, mutect2, varscan2
- DOCK7 | c.1801-1434C>T | Intron (SNP) | VAF 55/150 reads (37%) | called by muse, mutect2, varscan2
- EPHA5 | c.3008+647A>C | Intron (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- FOXG1 | c.*612A>G | 3'UTR (SNP) | VAF 43/101 reads (43%) | catalogued as rs565555663; called by muse, mutect2, varscan2
- GPR158 | c.*148A>G | 3'UTR (SNP) | VAF 45/92 reads (49%) | catalogued as COSV66268481; called by muse, mutect2, varscan2
- GPR158 | c.*969A>G | 3'UTR (SNP) | VAF 41/85 reads (48%) | catalogued as rs1272344074; called by muse, varscan2
- GPR158 | c.*1068T>G | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, varscan2
- GPR158 | c.*1253T>A | 3'UTR (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- HPS4 | chr22:26452044 T>A | 3'Flank (SNP) | VAF 15/36 reads (42%) | catalogued as rs2157585; called by muse, varscan2
- KLHL20 | c.*562A>G | 3'UTR (SNP) | VAF 56/123 reads (46%) | called by muse, mutect2, varscan2
- KRTAP9-7 | chr17:41271525 T>C | 5'Flank (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- LNPK | c.*3544T>C | 3'UTR (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- LTB | c.163-117_163-116del | Intron (DEL) | VAF 110/332 reads (33%) | catalogued as rs898774166; called by pindel, varscan2
- LZTFL1 | c.*2399C>T | 3'UTR (SNP) | VAF 60/149 reads (40%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1106A>T | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- MIR515-1 | n.80G>C | RNA (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- NOC2LP1 | n.1323C>T | RNA (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2
- NOC2LP2 | n.1030C>T | RNA (SNP) | VAF 14/76 reads (18%) | catalogued as rs770372735; called by muse, mutect2
- NPM2 | c.-131C>G | 5'UTR (SNP) | VAF 23/257 reads (9%) | called by muse, mutect2
- PANK4 | c.1374+169A>G | Intron (SNP) | VAF 77/184 reads (42%) | called by muse, mutect2, varscan2
- PEG10 | c.*3481T>A | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- PEX5L | c.*5326A>C | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49591598 C>T | 5'Flank (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- RFX3 | c.*1071G>A | 3'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- STK17B | c.*3312_*3315del | 3'UTR (DEL) | VAF 32/87 reads (37%) | called by mutect2, pindel, varscan2
- SYT1 | c.*1172A>C | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- TMEFF2 | c.439+2197G>A | Intron (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- TMEM68 | c.*1207A>G | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1282+41C>T | Intron (SNP) | VAF 64/155 reads (41%) | called by muse, mutect2, varscan2
- TRIM2 | chr4:153338941 G>A | 3'Flank (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- TRIM6 | c.875-55C>A | Intron (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- WNT5A | c.-189C>T | 5'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
